CCDI case PBBMJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/1a01d4b9-f015-43de-98ee-f83213e662f3

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 3.0 years (1,081 days).

Biospecimens (3 samples)
- Sample 0DCYO8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCYOB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCYOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
